Gene-level copy-number profile of tumor specimen C3L-01885-03 from CPTAC case C3L-01885, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 67.8 years (24,752 days).
Specimen C3L-01885-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 86d38db1-ebdc-453c-886c-4ba89fa46965.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-01885-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,217 have no estimate.
https://portal.gdc.cancer.gov/files/a98fe4e9-5392-440b-97fd-f10cf6baf37d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3,110; copy number 1: 1,914; copy number 2: 50,330; copy number 3: 151; copy number 4: 2,901.

Caution: 3,103 autosomal genes are at 0 copies in this file, far more than a typical tumor; the lists below are given as recorded.

Homozygous deletions (total copy number 0; autosomes only): 3,103 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,745–75,362,268, 1,237 genes (broad region; genes not listed).
- chr3:75,590,298–198,123,232, 1,852 genes (broad region; genes not listed).
- chr15:32,313,126–32,500,346, 14 genes: AC139426.1, AC139426.2, DNM1P31, GOLGA8K, RN7SL185P, AC135983.1, ULK4P1, U8, DNM1P32, GOLGA8O, RN7SL539P, AC135983.5, AC135983.4, AC135983.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,914. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
